Somatic mutation profile of tumor specimen MP2PRT-PAVWFL-TMP1-A (aliquot MP2PRT-PAVWFL-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVWFL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 6.1 years (2,217 days).
Specimen MP2PRT-PAVWFL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6abd67a-fe86-4ae8-bc21-0be651310a32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWFL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWFL-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf29c6db-253b-4f8a-b472-99d33cb8701c

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/250 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CDCP2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 136/740 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs759128689, COSV61282899; called by muse, mutect2, varscan2
- HMCN1 | c.9572G>A p.R3191H | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs368825571; called by muse, varscan2
- SLITRK3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1420153400, COSV53849228; called by muse, mutect2, varscan2
- WNT7A | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 342/688 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs373515267; called by muse, mutect2, varscan2
- CEP70 | c.15C>T p.A5= | Silent (SNP) | VAF 67/169 reads (40%) | catalogued as rs912875578, COSV99389694; called by muse, mutect2, varscan2
- ST8SIA3 | c.975A>G p.G325= | Silent (SNP) | VAF 164/344 reads (48%) | catalogued as COSV60654846; called by muse, mutect2
- WFIKKN1 | c.1344C>T p.P448= | Silent (SNP) | VAF 48/1038 reads (5%) | catalogued as rs776336011; called by muse, mutect2
